Somatic mutation profile of tumor specimen TCGA-85-6798-01A (aliquot TCGA-85-6798-01A-11D-1945-08) from TCGA case TCGA-85-6798, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 57.0 years (20,837 days).
Specimen TCGA-85-6798-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca9a3dc2-fe77-4901-978d-669a2e7ad54f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-6798-10A (Blood Derived Normal), aliquot TCGA-85-6798-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6a3a06f-576c-4c20-84c3-659fce64c141

The open-access MAF lists 306 somatic variants for this specimen: 230 protein-altering or splice-affecting, 67 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 67, Nonsense Mutation 11, Splice Site 8, Frame Shift Del 4, 3'UTR 3, RNA 3, Frame Shift Ins 3, 3'Flank 2, Splice Region 2, Translation Start Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 63/115 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 17/28 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD10 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as rs771784989, COSV56325241; called by muse, mutect2, varscan2
- AC006059.2 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100045795, COSV59605627; called by muse, mutect2, varscan2
- ACTN2 | c.2560C>G p.L854V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100856912; called by muse, mutect2, varscan2
- ADAP2 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100437326; called by muse, mutect2, varscan2
- AGO1 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV100940893; called by muse, mutect2, varscan2
- AGO4 | c.2174G>C p.R725T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as COSV100943037; called by muse, mutect2, varscan2
- AHNAK | c.17237C>G p.S5746* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV99948795; called by muse, mutect2, varscan2
- ANKFN1 | c.1918G>T p.V640L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs763328804, COSV100593921, COSV59453373, COSV59462313; called by mutect2, varscan2
- ANKRD44 | c.2803A>G p.I935V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.393); catalogued as rs1351048123, COSV99985652; called by muse, mutect2, varscan2
- ANKS1B | c.1794A>T p.K598N | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV100247092; called by muse, mutect2, varscan2
- APCDD1 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771067572, COSV100789996; called by muse, mutect2, varscan2
- ART4 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.127); catalogued as COSV99966951; called by muse, mutect2, varscan2
- ASTN1 | c.110T>A p.L37H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV99922614; called by muse, mutect2, varscan2
- ATL1 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs1207305110, COSV100220847; called by muse, mutect2, varscan2
- ATP4B | c.536T>G p.F179C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100089832; called by muse, mutect2, varscan2
- B3GNT3 | c.704T>A p.V235E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100427622; called by muse, mutect2, varscan2
- BCHE | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 92/129 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100012855; called by muse, mutect2, varscan2
- BPIFC | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239192121, COSV100301178; called by muse, mutect2, varscan2
- BRPF3 | c.1817A>T p.Q606L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100326062; called by muse, mutect2, varscan2
- BRWD1 | c.6306G>C p.R2102S | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV100313793; called by muse, mutect2, varscan2
- BTBD3 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99656023; called by muse, mutect2, varscan2
- C2orf69 | c.593G>C p.S198T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100178939; called by muse, mutect2, varscan2
- CACNA1A | c.5804T>C p.I1935T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100802985; called by muse, mutect2, varscan2
- CATSPERG | c.3263G>T p.C1088F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV99286793; called by muse, mutect2, varscan2
- CD163L1 | c.3895G>A p.A1299T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs772986676, COSV100550474; called by muse, mutect2, varscan2
- CDC14A | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325639; called by muse, mutect2, varscan2
- CDH12 | c.1257-1G>T p.X419_splice | Splice Site (SNP) | VAF 19/182 reads (10%) | catalogued as COSV101203096; called by muse, mutect2, varscan2
- CDH12 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1428435649, COSV101202564, COSV66419690; called by muse, mutect2
- CDH23 | c.6931C>T p.P2311S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); catalogued as rs1295012866, COSV56495375; called by muse, mutect2, varscan2
- CDH6 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.358); catalogued as COSV99420200; called by muse, mutect2, varscan2
- CDK8 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101037461; called by muse, mutect2, varscan2
- CENPF | c.5664G>T p.K1888N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100871846; called by muse, mutect2, varscan2
- CEP104 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100986683; called by muse, mutect2, varscan2
- CLVS1 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100370403, COSV57983897; called by muse, mutect2, varscan2
- CNGA1 | c.51T>A p.N17K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs748755294, COSV100652294; called by muse, mutect2, varscan2
- CNTNAP2 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs765970596, COSV100669155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.1145del p.G382Afs*10 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as COSV70482035; called by mutect2, pindel, varscan2
- COA5 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1305307057, COSV60830981; called by muse, mutect2, varscan2
- COL1A2 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV99800549; called by muse, mutect2, varscan2
- COL5A3 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as rs1229439408, COSV99319433; called by muse, mutect2, varscan2
- CRISPLD2 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV52284727, COSV99295910; called by muse, varscan2
- CSMD2 | c.5874C>G p.N1958K | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99593242; called by muse, mutect2, varscan2
- CSMD2 | c.3688G>C p.A1230P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV99593243; called by muse, mutect2, varscan2
- CSMD3 | c.10859C>G p.S3620* (on ENST00000297405 / NM_001363185.1; = p.S3451* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | catalogued as COSV52333333, COSV99842538; called by muse, mutect2, varscan2
- CYP4F12 | c.987C>T p.G329= | Splice Region (SNP) | VAF 12/35 reads (34%) | catalogued as COSV61176813; called by muse, mutect2, varscan2
- DDX18 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 19/117 reads (16%) | catalogued as COSV99604691; called by muse, mutect2, varscan2
- DISP2 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99140312; called by muse, mutect2, varscan2
- DNAH11 | c.5052G>T p.K1684N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV100180083, COSV60970675; called by muse, mutect2, varscan2
- DNAI1 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV99647026; called by muse, mutect2, varscan2
- DOK4 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191928697, COSV99538409; called by muse, mutect2, varscan2
- DRD2 | c.109T>A p.Y37N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100669935; called by muse, mutect2, varscan2
- DSP | c.6948C>A p.Y2316* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV101131582; called by muse, mutect2, varscan2
- DUSP21 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100173637, COSV59133941; called by muse, mutect2, varscan2
- DYSF | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs760585799, COSV50472303; called by muse, mutect2, varscan2
- EIF4A3 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53921612, COSV99484165; called by muse, mutect2, varscan2
- ENPP3 | c.10A>T p.T4S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs1383205517, COSV100717799; called by muse, mutect2, varscan2
- ESR1 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99065440, COSV99240402; called by muse, mutect2, varscan2
- ETS1 | c.453A>T p.E151D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as COSV100091136; called by muse, mutect2, varscan2
- EYS | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100676919; called by mutect2, varscan2
- FAM47A | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1181862055, COSV100650008; called by muse, varscan2
- FAM47A | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs5973088, COSV60494128, COSV60495398; called by muse, varscan2
- FAM81A | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99893478; called by muse, mutect2, varscan2
- FBLIM1 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181810; called by muse, mutect2, varscan2
- FBLN2 | c.2092G>T p.G698C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55482048, COSV99852383; called by muse, mutect2, varscan2
- FCER2 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100689622, COSV60917830; called by muse, mutect2, varscan2
- FCHO2 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.233); catalogued as rs750891864, COSV100530916; called by muse, mutect2
- FGA | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1207978312, COSV100120578; called by muse, mutect2, varscan2
- FLT3 | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99609712; called by muse, mutect2, varscan2
- GPR12 | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198007; called by muse, mutect2, varscan2
- GPR15 | c.842A>T p.Q281L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV99423899; called by muse, mutect2, varscan2
- GUSB | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100512713; called by muse, mutect2, varscan2
- HEPH | c.780G>C p.E260D (on ENST00000343002; = p.E314D on NM_138737.5) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV100295392; called by muse, mutect2, varscan2
- HERC2 | c.8804A>T p.D2935V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.715); catalogued as rs1435203979, COSV99875702; called by muse, mutect2, varscan2
- HFM1 | c.2125A>T p.I709F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99646486; called by muse, mutect2, varscan2
- HFM1 | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as COSV99646489; called by muse, mutect2, varscan2
- HIVEP3 | c.5393C>G p.T1798S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV56018286, COSV99913474; called by muse, mutect2, varscan2
- HOOK1 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100969185; called by muse, mutect2, varscan2
- HOXB5 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs977513559, COSV99494668; called by muse, mutect2, varscan2
- HSF5 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 85/148 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100090559; called by muse, mutect2, varscan2
- HTRA4 | c.1047C>G p.I349M | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100205859; called by muse, mutect2, varscan2
- IBTK | c.865G>T p.V289F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60390875, COSV60391556; called by muse, mutect2, varscan2
- IGSF10 | c.1968G>C p.L656F | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770562795, COSV99189515; called by muse, mutect2, varscan2
- ILF2 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100721984; called by muse, mutect2, varscan2
- IRF6 | c.968G>C p.W323S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884011; called by muse, mutect2, varscan2
- IRX4 | c.431C>G p.T144R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775659824, COSV99181141; called by muse, mutect2, varscan2
- ITPRID1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100087135; called by muse, mutect2
- KCNC1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789544; called by muse, mutect2, varscan2
- KIAA1522 | c.320C>T p.S107F (on ENST00000373480 / NM_001198972.2; = p.S166F on NM_020888.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53864651; called by muse, mutect2, varscan2
- KIF17 | c.2882T>A p.I961N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99929519; called by muse, mutect2, varscan2
- KLHL31 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763867568, COSV100911829; called by muse, mutect2, varscan2
- KRIT1 | c.1681A>G p.I561V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs146927768; called by muse, mutect2, varscan2
- KRTAP10-4 | c.980G>T p.S327I | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs782605437, COSV100554837; called by muse, mutect2, varscan2
- KRTAP5-1 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.632); catalogued as rs369053249, COSV101192925; called by muse, mutect2, varscan2
- LILRB1 | c.179-1G>T p.X60_splice (on ENST00000427581; = p.X24_splice on NM_006669.6) | Splice Site (SNP) | VAF 19/121 reads (16%) | catalogued as COSV100207628; called by muse, varscan2
- MAIP1 | c.743T>A p.V248D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99705303; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV100186647; called by muse, mutect2
- MAP2K3 | c.111C>A p.N37K (on ENST00000342679 / NM_145109.3; = p.N8K on NM_002756.4) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as COSV100384243; called by muse, mutect2, varscan2
- MAP3K21 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779367692, COSV64043697; called by muse, mutect2, varscan2
- MCM8 | c.149-2A>G p.X50_splice | Splice Site (SNP) | VAF 34/87 reads (39%) | catalogued as rs1190111898, COSV99177594; called by muse, mutect2, varscan2
- MGAM | c.2483C>A p.T828K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs762548545, COSV101527621; called by muse, mutect2, varscan2
- MICALL1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs200080428, COSV99317131; called by muse, mutect2, varscan2
- MNDA | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.378); catalogued as COSV100933410, COSV63741157; called by muse, mutect2, varscan2
- MPV17L | c.511G>A p.G171S (on ENST00000396385 / NM_001128423.2; = p.W147* on NM_173803.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as COSV99806270; called by muse, mutect2, varscan2
- MROH2B | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101270845; called by muse, mutect2, varscan2
- MTR | c.3286T>C p.Y1096H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV100855477; called by muse, mutect2, varscan2
- MUC16 | c.34147C>G p.P11383A | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.303); catalogued as COSV101200640; called by muse, mutect2, varscan2
- MUC16 | c.24283G>T p.D8095Y | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV101200641; called by muse, mutect2, varscan2
- MYBL1 | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1400355544, COSV101576586; called by muse, mutect2, varscan2
- MYBPC1 | c.2383T>C p.F795L (on ENST00000550270 / NM_206820.2; = p.F802L on NM_002465.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.461); catalogued as rs1398163617, COSV100638201; called by muse, mutect2, varscan2
- MYH9 | c.2286C>G p.F762L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99339495; called by muse, mutect2, varscan2
- MYT1L | c.2955C>A p.D985E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV101217316, COSV67701218; called by muse, mutect2, varscan2
- NAV3 | c.5297C>G p.A1766G | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.218); catalogued as COSV99890417, COSV99893896; called by muse, mutect2, varscan2
- NCOR2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369807577; called by muse, mutect2, varscan2
- NDUFA13 | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389202; called by muse, mutect2, varscan2
- NEB | c.8995A>G p.T2999A | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99425942; called by muse, mutect2, varscan2
- NES | c.4373T>A p.L1458Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100957945; called by muse, mutect2, varscan2
- NFATC2 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101044439; called by muse, mutect2, varscan2
- NLRP1 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99335043; called by muse, mutect2, varscan2
- NLRP13 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100738392; called by muse, mutect2, varscan2
- NOC4L | c.1073+1G>T p.X358_splice | Splice Site (SNP) | VAF 54/125 reads (43%) | catalogued as COSV100400170; called by muse, mutect2, varscan2
- NOS1 | c.1685T>A p.L562Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100501125; called by muse, mutect2, varscan2
- NPY1R | c.1123dup p.I375Nfs*5 | Frame Shift Ins (INS) | VAF 12/63 reads (19%) | catalogued as rs769517510; called by mutect2, varscan2
- OR10AG1 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV100400160; called by muse, mutect2
- OR10C1 | c.70C>T p.L24F (on ENST00000622521; = p.L22F on NM_013941.3) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV101010873; called by muse, mutect2, varscan2
- OR10G4 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100304919; called by muse, mutect2, varscan2
- OR2G2 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV100189862; called by muse, mutect2, varscan2
- OR2M7 | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV58740956; called by muse, mutect2, varscan2
- OR2T3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100613317; called by muse, mutect2, varscan2
- OR4D2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as COSV101613861; called by muse, mutect2, varscan2
- OR4K13 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100237826; called by muse, mutect2, varscan2
- OR5D18 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV100450464, COSV61737444; called by muse, mutect2, varscan2
- OR6F1 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV57469683; called by muse, mutect2, varscan2
- OR8B12 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV100172877; called by muse, mutect2
- OR8K5 | c.667T>G p.L223V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV57890845, COSV57891699; called by muse, mutect2, varscan2
- P2RX4 | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100465218; called by muse, mutect2, varscan2
- PADI2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs201884124, COSV64946580; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.538G>T p.E180* (on ENST00000259318 / NM_001136562.3; = p.E411* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV52172689, COSV99395539; called by muse, mutect2
- PCDHB16 | c.932T>C p.M311T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99502543; called by muse, mutect2, varscan2
- PCDHB4 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV52023102; called by muse, mutect2, varscan2
- PCNX2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs762362794, COSV99268842; called by muse, mutect2, varscan2
- PDE2A | c.1655T>C p.L552P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100558254; called by muse, mutect2, varscan2
- PDP2 | c.1112A>C p.E371A | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.155); catalogued as COSV100305983; called by muse, mutect2, varscan2
- PELP1 | c.2411C>G p.S804* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV52589196; called by muse, mutect2
- PHC3 | c.2340T>G p.S780R (on ENST00000494943 / NM_001308116.2; = p.S792R on NM_024947.4) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV101520181; called by muse, mutect2
- PHF3 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs200854574; called by muse, mutect2, varscan2
- PHOSPHO2 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99776047; called by muse, mutect2, varscan2
- PIK3C3 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.225); catalogued as COSV56284081; called by muse, mutect2, varscan2
- PLCB3 | c.2613G>C p.Q871H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99657628; called by muse, mutect2
- PLCH2 | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.458); catalogued as rs756323592, COSV99616837; called by muse, mutect2, varscan2
- PPIP5K2 | c.1937G>C p.S646T | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV100384088; called by muse, mutect2, varscan2
- PPM1B | c.1128T>A p.S376R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV99175855; called by muse, mutect2, varscan2
- PPP1R3A | c.3347A>C p.K1116T | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99493705; called by muse, mutect2, varscan2
- PPP1R3A | c.1523A>G p.E508G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99493708; called by muse, mutect2, varscan2
- PRKCB | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57807642; called by muse, mutect2, varscan2
- PROS1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV101260723; called by muse, varscan2
- PROSER3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV99994650; called by muse, mutect2, varscan2
- PSD2 | c.1971G>A p.E657= | Splice Region (SNP) | VAF 11/45 reads (24%) | catalogued as COSV51199111, COSV51214356; called by muse, mutect2, varscan2
- PTP4A3 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100267393; called by muse, mutect2, varscan2
- PTPRC | c.2557T>G p.C853G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722908; called by muse, mutect2, varscan2
- PTPRT | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100625517, COSV100629313; called by muse, mutect2, varscan2
- PXDNL | c.3590G>C p.W1197S | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100685297; called by muse, mutect2, varscan2
- RASAL1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as rs774212828, COSV99921996; called by muse, mutect2, varscan2
- RELN | c.9781T>G p.F3261V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.812); catalogued as COSV100634401; called by muse, mutect2, varscan2
- RFX4 | c.707C>G p.P236R (on ENST00000392842 / NM_213594.3; = p.P142R on NM_032491.6) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57578462; called by muse, mutect2, varscan2
- RNF139 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs751128494, COSV52678068; called by muse, mutect2, varscan2
- ROBO4 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1050106982; called by muse, mutect2
- RYR2 | c.3309T>A p.F1103L | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100772079; called by muse, mutect2, varscan2
- RYR2 | c.6370G>A p.G2124S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); catalogued as COSV100772080; called by muse, mutect2, varscan2
- SACS | c.11854G>C p.G3952R | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101207568; called by muse, mutect2, varscan2
- SACS | c.10645G>C p.E3549Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV101207569; called by muse, mutect2, varscan2
- SAMD9L | c.1040C>A p.A347D | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100561017; called by muse, mutect2, varscan2
- SCRN2 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99274225; called by muse, mutect2, varscan2
- SGPL1 | c.1620A>C p.E540D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV100940430; called by muse, mutect2, varscan2
- SIGLEC1 | c.1525A>G p.N509D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99169926; called by muse, mutect2, varscan2
- SLC22A16 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100397728; called by muse, mutect2, varscan2
- SLC22A25 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV60594661; called by muse, mutect2, varscan2
- SLC26A7 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV99403991; called by muse, mutect2, varscan2
- SLC38A11 | c.369+2T>A p.X123_splice (on ENST00000409149 / NM_001351539.1; = p.X101_splice on NM_173512.2) | Splice Site (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100366984; called by muse, mutect2, varscan2
- SLC45A1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs766677852, COSV57094390; called by muse, mutect2, varscan2
- SLC52A1 | c.1043T>G p.L348R | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99643492; called by muse, mutect2, varscan2
- SLC6A15 | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99881309; called by muse, mutect2, varscan2
- SMC4 | c.2164G>C p.D722H | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100644099; called by muse, mutect2, varscan2
- SNX10 | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100640119; called by muse, mutect2, varscan2
- SRL | c.287T>A p.V96E | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101281361; called by muse, mutect2, varscan2
- STARD13 | c.2366T>G p.L789R (on ENST00000336934 / NM_001243476.3; = p.L671R on NM_052851.3) | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716218; called by muse, mutect2, varscan2
- STIL | c.1041C>G p.D347E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV99681184; called by muse, mutect2, varscan2
- SUPT6H | c.484A>T p.M162L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs776052881, COSV100112627; called by muse, mutect2, varscan2
- SYNE1 | c.7484A>G p.E2495G (on ENST00000367255 / NM_182961.4; = p.E2502G on NM_033071.3) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1055070356, COSV54966819, COSV99572322; called by muse, mutect2, varscan2
- TAAR1 | c.16C>G p.H6D | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV99257697; called by muse, mutect2, varscan2
- TCF20 | c.5461G>A p.V1821I | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100166821; called by muse, mutect2, varscan2
- TCF3 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99514366; called by muse, mutect2, varscan2
- TCIRG1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99693532; called by muse, mutect2
- TEP1 | c.5004-2A>G p.X1668_splice | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99402945; called by muse, mutect2, varscan2
- TEX19 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100331072; called by muse, mutect2, varscan2
- TJP1 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as COSV100632986; called by muse, mutect2, varscan2
- TJP3 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs578221094, COSV99516362; called by muse, mutect2, varscan2
- TM7SF3 | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100544934; called by muse, varscan2
- TM7SF3 | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100544936; called by muse, varscan2
- TM7SF3 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); catalogued as COSV100544938; called by muse, varscan2
- TMCO3 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100952390; called by muse, mutect2, varscan2
- TMCO4 | c.314A>T p.K105M | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV99617257; called by muse, mutect2, varscan2
- TRIM36 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs543104439, COSV56690440, COSV56694152; called by muse, mutect2, varscan2
- TRIM38 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.268); catalogued as COSV100837617; called by muse, mutect2
- TRPA1 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as COSV100084833; called by muse, mutect2, varscan2
- TTN | c.99250G>C p.D33084H (on ENST00000591111; = p.D25660H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/183 reads (10%) | PolyPhen benign (0.346); catalogued as COSV100623143; called by muse, mutect2
- UBA3 | c.830A>G p.H277R | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734744; called by muse, mutect2, varscan2
- UPK1B | c.166T>G p.Y56D | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV99953758; called by muse, mutect2, varscan2
- VPS13A | c.5527A>G p.I1843V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV100653204; called by muse, mutect2, varscan2
- VPS13B | c.2137C>T p.H713Y | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs796181999, COSV100662899; called by muse, mutect2, varscan2
- VPS52 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1283456787, COSV69385199; called by muse, mutect2, varscan2
- WDR17 | c.2662G>T p.D888Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV99708038; called by muse, mutect2, varscan2
- WWC3 | c.2862C>A p.C954* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV101081649; called by muse, mutect2
- ZNF239 | c.943G>T p.G315* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100021859; called by muse, mutect2, varscan2
- ZNF493 | c.1907T>C p.I636T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1421003143, COSV100828812; called by muse, mutect2, varscan2
- ZNF519 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.094); catalogued as COSV101645570; called by muse, mutect2
- ZNF595 | c.826A>G p.K276E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.622); catalogued as rs1553801462, COSV100227836; called by muse, varscan2
- ZNF609 | c.1062-2A>G p.X354_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100441517; called by muse, mutect2, varscan2
- ZNF770 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100696017; called by muse, mutect2, varscan2
- ZSWIM1 | c.995C>G p.A332G | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV54846810, COSV54850309; called by muse, mutect2, varscan2
- ZSWIM2 | c.387T>A p.H129Q | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV99720403; called by muse, mutect2, varscan2
- FAM135B | c.3051dup p.E1018Rfs*69 | Frame Shift Ins (INS) | VAF 26/52 reads (50%) | called by mutect2, pindel, varscan2
- HTR5A | c.499del p.A167Hfs*28 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KCNB1 | c.1224del p.I409Sfs*40 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- MBD5 | c.74_75del p.W25Sfs*26 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | called by mutect2, pindel, varscan2
- PRAMEF6 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RB1 | c.2201_2202dup p.V735Lfs*10 | Frame Shift Ins (INS) | VAF 36/74 reads (49%) | called by mutect2, pindel, varscan2
- TRIM5 | c.514-2A>G p.X172_splice | Splice Site (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2
- ADAM12 | c.2412C>A p.L804= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV100903474; called by muse, mutect2, varscan2
- AIPL1 | c.351C>T p.H117= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs370312709; called by muse, mutect2, varscan2
- APPL1 | c.495A>G p.E165= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99897902; called by muse, mutect2, varscan2
- ATF6 | c.1776A>G p.S592= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100909353, COSV63406196; called by muse, mutect2, varscan2
- B3GNT3 | c.705G>A p.V235= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100427623; called by muse, mutect2, varscan2
- BMP6 | c.1467T>G p.L489= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV99307307; called by muse, mutect2, varscan2
- C3orf22 | c.111C>A p.P37= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100559543; called by muse, mutect2, varscan2
- CADM3 | c.156G>A p.V52= (on ENST00000368125 / NM_001127173.3; = p.V86= on NM_021189.5) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV63687394; called by muse, mutect2, varscan2
- CATIP | c.780G>A p.V260= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99179594; called by muse, mutect2, varscan2
- CDK4 | c.312G>A p.L104= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV99226084; called by muse, mutect2, varscan2
- CDYL2 | c.633C>T p.N211= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs776719928, COSV101629605; called by muse, mutect2, varscan2
- CHST12 | c.930G>T p.P310= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV51678982, COSV99324603; called by muse, mutect2, varscan2
- CHST3 | c.630G>T p.L210= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100910505; called by muse, mutect2, varscan2
- COL16A1 | c.4005A>T p.G1335= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99595095; called by muse, mutect2, varscan2
- CSMD1 | c.1923C>G p.V641= (on ENST00000520002; = p.V640= on NM_033225.6) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1268081822, COSV100151800; called by muse, mutect2, varscan2
- CXCR3 | c.534C>A p.L178= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101031700; called by muse, mutect2, varscan2
- DST | c.20460G>T p.S6820= (on ENST00000361203 / NM_001374722.1; = p.S4517= on NM_015548.5) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99758594; called by muse, mutect2, varscan2
- EXPH5 | c.3234G>A p.A1078= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs746668109, COSV99761987; called by muse, mutect2, varscan2
- FAT3 | c.3522T>C p.D1174= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99968612; called by muse, mutect2, varscan2
- FBXL4 | c.177G>A p.V59= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV100014300; called by muse, mutect2, varscan2
- FHOD3 | c.867G>T p.L289= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99942184; called by muse, mutect2
- FSD2 | c.1002C>T p.F334= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100575240; called by muse, mutect2, varscan2
- GFOD1 | c.1140C>T p.A380= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV101015173; called by muse, mutect2, varscan2
- GRK1 | c.387G>T p.G129= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV100175419; called by muse, mutect2, varscan2
- HAVCR1 | c.753C>A p.T251= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV100208490; called by muse, mutect2, varscan2
- HCN2 | c.795C>A p.T265= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99241331, COSV99242155; called by muse, mutect2, varscan2
- HNRNPDL | c.868T>C p.L290= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs952943412, COSV99787179; called by muse, mutect2, varscan2
- IGHV1-24 | c.216T>C p.P72= | Silent (SNP) | VAF 116/255 reads (45%) | catalogued as rs1555470106; called by muse, mutect2, varscan2
- IGKV3-15 | c.195G>A p.R65= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs558649365; called by muse, mutect2, varscan2
- IL1R1 | c.501A>T p.L167= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99292776; called by muse, mutect2, varscan2
- INHBA | c.123C>A p.A41= | Silent (SNP) | VAF 29/379 reads (8%) | catalogued as rs1196760597, COSV54220396, COSV99638110; called by muse, mutect2
- ITSN2 | c.2613A>T p.T871= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100743964; called by muse, mutect2, varscan2
- JMJD1C | c.1374A>G p.E458= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV101232448; called by muse, mutect2, varscan2
- KRT20 | c.1017G>A p.L339= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV99391521; called by muse, mutect2, varscan2
- KRTAP10-4 | c.429A>T p.S143= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV100554835; called by muse, mutect2, varscan2
- MAP3K19 | c.81T>C p.D27= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100208983; called by muse, mutect2
- ME3 | c.1482C>T p.P494= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs758225028, COSV62775433; called by muse, mutect2, varscan2
- MOCS3 | c.615C>A p.A205= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99724445; called by muse, mutect2, varscan2
- MRPS5 | c.1041G>A p.Q347= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as COSV99720963; called by muse, mutect2, varscan2
- MYO5C | c.2940A>G p.Q980= | Silent (SNP) | VAF 46/81 reads (57%) | catalogued as COSV99955163; called by muse, mutect2, varscan2
- NBEA | c.5460C>A p.G1820= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV100082741; called by muse, mutect2, varscan2
- NCOA2 | c.2556T>C p.P852= | Silent (SNP) | VAF 21/238 reads (9%) | catalogued as COSV99144993; called by muse, mutect2
- NDUFS7 | c.258G>T p.L86= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99282952; called by muse, mutect2, varscan2
- NR0B2 | c.291G>C p.L97= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- OR11G2 | c.594C>T p.I198= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV62132282; called by muse, mutect2, varscan2
- OR1S1 | c.561C>G p.L187= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100515462; called by muse, mutect2, varscan2
- OR5T3 | c.777A>T p.G259= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100282885, COSV57380454; called by muse, mutect2, varscan2
- OR6F1 | c.345G>T p.L115= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100129093; called by muse, mutect2, varscan2
- OR6V1 | c.477C>G p.L159= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV101389474; called by muse, mutect2, varscan2
- PARP14 | c.588A>G p.Q196= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV101506323; called by muse, mutect2, varscan2
- PRKAR1A | c.513G>C p.G171= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV100675227; called by muse, mutect2, varscan2
- PRKCB | c.1551C>T p.P517= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100334826; called by muse, mutect2, varscan2
- RBMXL2 | c.816T>C p.D272= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100182410; called by muse, mutect2, varscan2
- RHEX | c.360C>T p.D120= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100520201; called by muse, mutect2, varscan2
- SIGLEC12 | c.183C>G p.G61= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV52463478, COSV99389504; called by muse, mutect2, varscan2
- SLC12A5 | c.1521A>G p.P507= (on ENST00000454036 / NM_001134771.2; = p.P484= on NM_020708.5) | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as COSV99716525; called by muse, mutect2, varscan2
- SLC17A8 | c.1380T>C p.S460= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs771049638, COSV100035729; called by muse, mutect2, varscan2
- SMG1 | c.5565C>G p.L1855= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV101246630; called by muse, mutect2, varscan2
- STEAP4 | c.174G>T p.L58= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV100112664; called by muse, mutect2, varscan2
- SYNE1 | c.3795T>A p.T1265= (on ENST00000367255 / NM_182961.4; = p.T1272= on NM_033071.3) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99573589; called by muse, mutect2, varscan2
- TTN | c.57213C>G p.S19071= (on ENST00000591111; = p.S11647= on NM_003319.4) | Silent (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- TYR | c.1474C>T p.L492= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99634933; called by muse, mutect2, varscan2
- UMODL1 | c.1557C>T p.C519= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100210785; called by muse, mutect2, varscan2
- WT1 | c.1014C>T p.C338= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as CM041490, COSV100188605; called by muse, mutect2, varscan2
- ZMYM4 | c.930A>G p.P310= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs770584821, COSV100110937, COSV58916623; called by mutect2, varscan2
- ZNF318 | c.4956C>A p.A1652= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as COSV100546409; called by muse, mutect2, varscan2
- ZNF423 | c.3204G>A p.L1068= (on ENST00000563137 / NM_001379286.1; = p.L1060= on NM_015069.4) | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs1237588948, COSV99283033; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701174 T>A | 3'Flank (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- KLRC3 | c.678+21T>C | Intron (SNP) | VAF 7/35 reads (20%) | catalogued as COSV101122925; called by muse, mutect2, varscan2
- LINC00518 | n.737C>G | RNA (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- POM121 | chr7:72949054 G>A | 3'Flank (SNP) | VAF 22/70 reads (31%) | catalogued as rs150808402; called by muse, mutect2, varscan2
- RALB | c.*2T>A | 3'UTR (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99732787; called by muse, mutect2, varscan2
- RELCH | c.*2A>G | 3'UTR (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99902562; called by muse, mutect2, varscan2
- RPL23AP42 | n.389C>T | RNA (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- SNORD116-12 | n.68C>T | RNA (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- VNN3 | c.*138C>A | 3'UTR (SNP) | VAF 36/130 reads (28%) | catalogued as COSV99258501; called by muse, mutect2, varscan2
